Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29W, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29W-06A (Metastatic).

[page 1 of 2]
DOB/Age/Sex
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:

HISTOPATHOLOGY REPORT

REFERRED MRN

CLINICAL DETAILS

Melanoma groin lymph nodes. Right.
Right ilio inguinal dissection. - inguinal. - common/ext. iliac LN dissection. - obturator.

FROZEN SECTION REPORT

Fresh tissue was taken for tumour banking (Registrar/ Pathologist:

MACROSCOPIC DESCRIPTION

(Dr

Two specimens received.

1. "RIGHT INGUINAL DISSECTION STITCH LONG PROXIMAL, LOOP DISTAL, RIGHT ILIO INGUINAL DISSECTION". The specimen is a piece of fibrofatty tissue, measuring 135 x 45 x 22mm. There is an overlying skin ellipse, measuring 100 x 21mm. The skin ellipse contains a pale papule, measuring 5 x 4mm (block K). There are two long sutures at one end, allocated as proximal. There is a loosely attached suture with a loop at the middle of the specimen allocated as distal. In the middle of the specimen there is blue marking, it appears that sampling for tissue banking has been taken place over there. The nodular deposit measures 20 x 13 x 13mm. Sectioning has been taken from proximal to distal.

- A. One bisected lymph node.
- B. One lymph node.
- C. One lymph node.
- D. One lymph node.
- E. One lymph node.
- F. One lymph node.
- G. One bisected lymph node.
- H. One dissected lymph node.
- J. One lymph node.
- K. Skin papular, bisected.
- L-N. Largest lymph node of specimen (tumour bank).

1CD-0-3

Melanoma, NOS 8720/3

Site: lymph node, inguinal

C77.4

6/2/11

2. "RIGHT ILIAC OBTURATOR NODES". The specimen consists of fibrofatty tissue, measuring 75 x 48 x 35mm.

- A & B. One bisected lymph node.
- C. One lymph node.
- D. One lymph node.
- E & F. One possible bisected lymph node.
- G. One lymph node
- H & J. One possible bisected lymph node.

A Unit of

Printed

Page 1 of 2

This fax was received by

[page 2 of 2]
Requested by

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

K. One possible lymph node.

MICROSCOPIC REPORT**1. "RIGHT INGUINAL DISSECTION".**

Microscopy of the tumour nodule seen grossly shows malignant tumour consistent with melanoma. The tumour is composed of sheets of epithelioid cells with hyperchromatic nuclei. Mitotic figures are readily identified. The tumour infiltrates adipose tissue. There is an adjacent lymph node but no convincing residual nodal tissue is identified in the large deposit and it is unclear if this is a nodal deposit or a soft tissue deposit of melanoma. An additional nine lymph nodes are seen, one of which shows fibrous capsular-type tissue but is otherwise entirely replaced by malignant tumour consistent with melanoma.

The skin papule seen grossly shows features in keeping with an intradermal naevus.

Immunohistochemical studies have been performed on the largest tumour deposit. The tumour stains positively for S-100, supporting a diagnosis of melanoma. Immunostains for HMB45 and Melan A are negative.

2. "RIGHT ILIAC OBTURATOR NODES".

Seven lymph nodes are identified. No metastatic melanoma is seen.

SUMMARY**1. RIGHT INGUINAL LYMPH NODE DISSECTION:**

Two deposits of metastatic melanoma (2/10), largest 20mm in diameter.
Extranodal extension is seen.

2. RIGHT ILIAC OBTURATOR LYMPH NODES:

Seven lymph nodes, no evidence of malignancy seen (0/7).

REPORTED BY: Dr

Source: NCI Genomic Data Commons file 766581b2-4982-4bcc-9f11-e05f14225654 (TCGA-EE-A29W.E700FE5C-7451-4C73-A966-8382C08C51F1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).